Somatic mutation profile of tumor specimen TCGA-P5-A731-01A (aliquot TCGA-P5-A731-01A-11D-A32B-08) from TCGA case TCGA-P5-A731, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 59.5 years (21,715 days).
Specimen TCGA-P5-A731-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be440254-8860-430d-9131-6266de3423a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P5-A731-10A (Blood Derived Normal), aliquot TCGA-P5-A731-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1027b1b1-0b75-477f-b445-596a379913ee

The open-access MAF lists 25 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 19, Silent 4, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 20/64 reads (31%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- CDH17 | c.1067G>T p.G356V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV99217962; called by muse, mutect2, varscan2
- CEACAM6 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as rs781942066, COSV99555727; called by muse, mutect2, varscan2
- CLDND1 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.513); catalogued as rs761957957, COSV57858154, COSV57858167; called by muse, mutect2, varscan2
- CMIP | c.1830G>C p.E610D (on ENST00000537098 / NM_198390.2; = p.E516D on NM_030629.3) | Missense Mutation (SNP) | VAF 66/186 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV101220960; called by muse, mutect2, varscan2
- CRYBG2 | c.1082T>C p.V361A | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as rs1413755748; called by muse, mutect2, varscan2
- DSP | c.3512T>C p.I1171T | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs762449180, COSV101131724; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM47C | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs781884172, COSV63723626; called by muse, mutect2, varscan2
- HPRT1 | c.442T>C p.S148P | Missense Mutation (SNP) | VAF 93/231 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100053295; called by muse, mutect2, varscan2
- HUWE1 | c.8751C>G p.S2917R | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV99472534, COSV99474080; called by muse, mutect2, varscan2
- KIF5C | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs749228157, COSV101469561; called by muse, mutect2, varscan2
- KMT2C | c.523G>T p.D175Y | Missense Mutation (SNP) | VAF 80/387 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV100076144, COSV51499295; called by muse, mutect2, varscan2
- LTA4H | c.1483C>T p.L495F | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV57383410, COSV99957307; called by muse, mutect2, varscan2
- MRPS23 | c.259C>A p.L87I | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100551485; called by muse, mutect2, varscan2
- MYH8 | c.4808C>T p.T1603M | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs775820322, COSV101238732; called by muse, mutect2, varscan2
- RSPH14 | c.904G>A p.A302T | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.177); catalogued as COSV53271017, COSV99321181; called by muse, mutect2, varscan2
- SIRT1 | c.1271G>C p.R424T | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV99282026; called by muse, mutect2, varscan2
- STAB1 | c.1489G>A p.A497T | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV100402180; called by muse, mutect2, varscan2
- GPX2 | c.260dup p.Y88Vfs*? | Frame Shift Ins (INS) | VAF 12/46 reads (26%) | called by mutect2, pindel, varscan2
- TMEFF1 | c.1125del p.S376Hfs*17 | Frame Shift Del (DEL) | VAF 19/91 reads (21%) | called by mutect2, pindel, varscan2
- TRAV9-2 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2
- DDX54 | c.630T>C p.F210= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV100014169; called by muse, mutect2, varscan2
- OXR1 | c.540C>T p.V180= (on ENST00000442977 / NM_001198532.1; = p.V179= on NM_018002.3) | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV100367691; called by muse, mutect2, varscan2
- TMC3 | c.2328A>G p.S776= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as COSV100846008; called by muse, mutect2
- ZNF569 | c.2025G>A p.S675= | Silent (SNP) | VAF 51/125 reads (41%) | catalogued as rs780514993, COSV57600307; called by muse, mutect2, varscan2
